Somatic mutation profile of tumor specimen TCGA-61-1725-01A (aliquot TCGA-61-1725-01A-01W-0639-09) from TCGA case TCGA-61-1725, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 40.5 years (14,782 days).
Specimen TCGA-61-1725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 612d61f6-c73f-41ca-b04c-800ccae9e29c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1725-11A (Solid Tissue Normal), aliquot TCGA-61-1725-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dbb7c2b-0463-4458-a68a-a47b5f8c51e0

The open-access MAF lists 64 somatic variants for this specimen: 54 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 45, Silent 10, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.721T>G p.S241A | Missense Mutation (SNP) | VAF 33/49 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520002, CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABHD10 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as COSV56325293; called by muse, mutect2, varscan2
- AGTPBP1 | c.3365A>G p.E1122G (on ENST00000357081 / NM_001330701.2; = p.E1082G on NM_015239.2) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100429247; called by muse, mutect2, varscan2
- ALDH1B1 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV66619999; called by muse, mutect2, varscan2
- C12orf40 | c.1106A>C p.E369A | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV61133162; called by muse, mutect2, varscan2
- CCDC191 | c.2459A>C p.Q820P | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV55672725; called by muse, mutect2, varscan2
- CCDC80 | c.1666A>T p.N556Y | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV52817288; called by muse, mutect2, varscan2
- CENPE | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 30/43 reads (70%) | catalogued as COSV54382263; called by muse, mutect2, varscan2
- DPP3 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100855428; called by muse, mutect2
- DYNC2H1 | c.3586A>C p.I1196L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV62095711; called by muse, mutect2, varscan2
- EPS8 | c.1183A>C p.N395H | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV55531662; called by muse, mutect2, varscan2
- FAM47A | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1200250652, COSV60497293; called by muse, mutect2, varscan2
- FAT2 | c.6046C>T p.Q2016* | Nonsense Mutation (SNP) | VAF 56/190 reads (29%) | catalogued as COSV55820975; called by muse, mutect2, varscan2
- FBXO24 | c.748G>A p.V250M (on ENST00000241071 / NM_033506.3; = p.V288M on NM_012172.5) | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as rs766050129, COSV53826584; called by muse, mutect2, varscan2
- GDPD3 | c.702C>G p.I234M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.672); catalogued as COSV53774071; called by muse, mutect2, varscan2
- GLCE | c.1636A>C p.K546Q | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55946254; called by muse, mutect2, varscan2
- GPR160 | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV63473013; called by muse, mutect2, varscan2
- HMCN1 | c.5756C>G p.P1919R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54905599; called by muse, mutect2, varscan2
- ICOS | c.563C>G p.T188R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV57030051; called by muse, mutect2, varscan2
- JAK3 | c.2863A>T p.I955F | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV71686101; called by muse, mutect2, varscan2
- JUN | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.358); catalogued as rs1158688004, COSV100973371, COSV64665143; called by muse, mutect2
- MEGF10 | c.2032A>G p.N678D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57250190; called by muse, mutect2, varscan2
- MUC21 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.069); catalogued as rs142512316; called by muse, varscan2
- NELFE | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV100952586; called by muse, mutect2
- NSFL1C | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV99401172; called by muse, mutect2
- PCDH1 | c.2665G>C p.G889R | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54614660; called by muse, mutect2, varscan2
- PCDHB7 | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV50754443, COSV50773910, COSV50774305; called by muse, mutect2, varscan2
- PCDHGA3 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV53961703, COSV54053494; called by muse, mutect2, varscan2
- PCED1B | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV71395274; called by mutect2, varscan2
- PCSK9 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.518); catalogued as COSV56162525; called by muse, mutect2, varscan2
- PLP1 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 18/313 reads (6%) | catalogued as CM128731, COSV100393249; called by muse, mutect2
- PLXND1 | c.1981T>C p.C661R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100139031; called by muse, mutect2, varscan2
- PPP2R5E | c.234C>A p.D78E | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.699); catalogued as COSV61742235; called by muse, mutect2, varscan2
- PSAP | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV56468433; called by muse, mutect2, varscan2
- RABGGTA | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV53770617; called by muse, mutect2, varscan2
- RAD17 | c.769A>T p.I257L (on ENST00000380774 / NM_133339.2; = p.I246L on NM_002873.1) | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV51458085; called by muse, mutect2, varscan2
- RPGRIP1L | c.2205A>C p.L735F | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50907943; called by muse, mutect2, varscan2
- SLAIN1 | c.1556G>T p.S519I (on ENST00000466548; = p.S256I on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57387169; called by muse, varscan2
- SP100 | c.618G>C p.E206D | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV50981739; called by muse, mutect2, varscan2
- TMCC1 | c.1803G>C p.L601F (on ENST00000393238 / NM_001349268.2; = p.L277F on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61440852; called by muse, mutect2, varscan2
- TRPS1 | c.629C>T p.P210L (on ENST00000220888 / NM_001330599.2; = p.P223L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/266 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV55263621; called by muse, mutect2
- TRPS1 | c.628C>T p.P210S (on ENST00000220888 / NM_001330599.2; = p.P223S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/262 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99634282; called by muse, mutect2
- TTN | c.14957C>A p.A4986D (on ENST00000591111; = p.A4059D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | PolyPhen benign (0.079); catalogued as COSV100594277; called by muse, mutect2
- TVP23B | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.031); catalogued as COSV57060062; called by muse, mutect2, varscan2
- USP7 | c.1501C>T p.H501Y | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV61215035; called by muse, mutect2, varscan2
- ZBTB37 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62932551; called by muse, mutect2, varscan2
- ZC3HAV1 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99648236; called by mutect2, varscan2
- ZKSCAN5 | c.1097G>C p.R366P | Missense Mutation (SNP) | VAF 13/269 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100460017, COSV58742885; called by muse, mutect2
- ZNF613 | c.1777G>A p.E593K (on ENST00000293471 / NM_001031721.4; = p.E557K on NM_024840.4) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs753762132, COSV53272260, COSV99523049; called by muse, mutect2, varscan2
- FAM153A | c.772-1_772del p.X258_splice | Splice Site (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- HMCN1 | c.5301-8_5306del p.X1767_splice | Splice Site (DEL) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- KNTC1 | c.2815_2840del p.Q939Gfs*17 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, varscan2
- NF1 | c.1387del p.A463Hfs*10 | Frame Shift Del (DEL) | VAF 36/66 reads (55%) | called by mutect2, pindel, varscan2
- SEMA3D | c.138_143delinsTA p.K46Nfs*29 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by pindel, varscan2*
- ABCA12 | c.2883T>A p.P961= (on ENST00000272895 / NM_173076.3; = p.P643= on NM_015657.3) | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV55961633; called by muse, mutect2, varscan2
- AGTPBP1 | c.3366A>G p.E1122= (on ENST00000357081 / NM_001330701.2; = p.E1082= on NM_015239.2) | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100429242; called by muse, mutect2, varscan2
- CCDC69 | c.636G>A p.L212= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100815080, COSV100815185; called by muse, mutect2, varscan2
- CCR9 | c.1041A>T p.T347= (on ENST00000357632 / NM_031200.3; = p.T335= on NM_006641.4) | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100591572; called by muse, mutect2
- FASTKD3 | c.1185T>G p.T395= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV52944314; called by muse, mutect2, varscan2
- GNPTG | c.777G>T p.L259= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV50190153, COSV50190916; called by muse, mutect2, varscan2
- PHIP | c.4971G>A p.K1657= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV51505301; called by muse, mutect2, varscan2
- PLXNA4 | c.3522G>A p.G1174= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV58131297; called by muse, mutect2, varscan2
- PPIC | c.525C>T p.S175= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as COSV100120532; called by muse, mutect2
- TCF12 | c.1452T>C p.S484= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV51008077; called by muse, mutect2, varscan2
